Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A68G, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A68G-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:

PATIENT NBR:

PAGE #: 1
SEX: M

ACCESSION:

REQ DOC:

PROCEDURE: SPHS

VERIFIED BY:

Patient with diagnosis of pheochromocytoma. Operative Procedure/Tissue
Submitted: Laparoscopic right adrenalectomy.

PROCEDURE: SPGD

VERIFIED BY:

1. "Right adrenal gland" Received in formalin in a medium container is a 68.38 gram, 14.5 x 7 x 1 cm adrenal gland and multiple fragments of fibroadipose tissue, 5.5 x 5.5 x 1.8 cm in aggregate. Exterior of the specimen is smooth, with attached adipose tissue. Serial sectioning reveals a 2 x 1.2 x 1.5 cm discrete nodule within the adrenal gland. The cut surface is mottled white-red with areas of potential necrosis. The nodule appears completely confined by the adrenal gland. Remainder of the adrenal gland parenchyma shows no gross abnormalities. Evaluation of the attached and the separately submitted adipose tissue reveals no lymph nodes.

1A-E. Serial sections of mass.

1F. Representative section of apparently uninvolved adrenal parenchyma.

PROCEDURE: SPDX

VERIFIED BY

1. Right adrenal gland, resection: Pheochromocytoma (2 cm) contained within adrenal gland.

I, the signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

	Yes	No
AA Discrepancy		
or Malignancy History		
1/Synchronous Primary Noted		

Source: NCI Genomic Data Commons file 4085603e-08d5-4f3f-9c23-c5e609e90ad3 (TCGA-RW-A68G.B7D7332B-1F53-4759-BFB5-FC428101F753.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).